MMRF case MMRF_2302 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dab8b8e1-694b-4faa-bffd-a227b8526c13

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.7 years (28,367 days); Days to last known disease status: 821 days (2.2 years); Days to last follow up: 821 days (2.2 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 264 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 283 days; Days to treatment end: 325 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 376 days (1.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.69 mg/dL; Immunoglobulin G 1.65 g/L; Immunoglobulin A 45.9 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 3.68 ×10⁹/L; Absolute Neutrophil 1.92 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Albumin 30 g/L; Total Protein 9.1 g/dL; Glucose 4.62 mmol/L.
- Day 89 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.05 mg/dL; Immunoglobulin G 2 g/L; Immunoglobulin A 17.7 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.49 ×10⁹/L; Absolute Neutrophil 1.78 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.05 mmol/L; Albumin 31 g/L; Total Protein 6.7 g/dL; Glucose 6.11 mmol/L.
- Day 173 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.08 mg/dL; Immunoglobulin G 1.76 g/L; Immunoglobulin A 6.15 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.23 ×10⁹/L; Absolute Neutrophil 2.75 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 6 g/dL; Glucose 4.29 mmol/L.
- Day 283 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 3.76 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 7.03 ×10⁹/L; Absolute Neutrophil 3.19 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 4.73 mmol/L.
- Day 376 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 4.48 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 4.33 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.12 ×10⁹/L; Absolute Neutrophil 1.97 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 6.16 mmol/L.
- Day 467 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 0.13 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 6.84 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.46 ×10⁹/L; Absolute Neutrophil 1.22 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 4.51 mmol/L.
- Day 558: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 8.34 g/L; Immunoglobulin A 1.55 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.95 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 4.9 mmol/L.
- Day 649: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1.73 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.22 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 5.78 mmol/L.
- Day 821 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 3.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Hemoglobin 8.74 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.54 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 4.13 mmol/L.

Other clinical attributes
- Day -2: Weight: 88 kg; Height: 179 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2302_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_2302_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
